Surgical pathology report (de-identified scan), TCGA case TCGA-4Z-AA84, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-4Z-AA84-01A (Primary Tumor).

ICD-O-3
Carcinoma, urothelial NOS
8/20/13
Site Bladder NOS
C67.9
JW 3/18/14

Collect date
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Bladder

Product partial cystectomy:

- Urothelial high grade carcinoma, extensively necrotic, infiltrating into the perivesical adipose tissue.
- Surgical margins uninvolved, but close at top left portion (1.9 mm).
- Angiolymphatic infiltration: present.
- Perineural infiltration: not detected.
- Absence of neoplastic infiltration of the right and left ureter and on the rectal wall fragment.
- Presence of metastases in two lymph nodes dissected (2/2).
- Pathological staging: pT3b, pN2, pMX.

Source: NCI Genomic Data Commons file d3224304-ffb4-4a50-8bd3-113678425d4e (TCGA-4Z-AA84.528501A3-F7C9-4D93-AC98-7CFFF0C11D0A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).